Somatic mutation profile of tumor specimen MP2PRT-PASMPE-TMP1-A (aliquot MP2PRT-PASMPE-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASMPE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Precursor B-cell lymphoblastic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.7 years (3,543 days).
Specimen MP2PRT-PASMPE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75242575-676b-47e9-b6e6-7a1e7e2cd9cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASMPE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASMPE-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0b9d4c3-5b3d-4a63-9cc1-3906e2123c97

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 103/268 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.159); catalogued as rs397507540, CM053389, CM067454, COSV61004831; ClinVar: pathogenic; called by muse, varscan2
- SETD2 | c.4715+1G>C p.X1572_splice | Splice Site (SNP) | VAF 80/197 reads (41%) | hotspot (GDC flag); catalogued as rs1485723437, COSV57431126, COSV57439397; called by muse, mutect2, varscan2
- ADAMTS15 | c.2102C>T p.A701V | Missense Mutation (SNP) | VAF 85/222 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs759505700; called by muse, mutect2, varscan2
- CHPF | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 183/448 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.168); catalogued as rs750764885, COSV60535947; called by muse, mutect2, varscan2
- CRACR2B | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 192/527 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs546770617, COSV58989371; called by muse, mutect2, varscan2
- PKLR | c.1493G>T p.R498L | Missense Mutation (SNP) | VAF 197/473 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as CM941169, COSV61362757; called by muse, mutect2, varscan2
- TMC4 | c.1384G>T p.D462Y (on ENST00000617472 / NM_001145303.3; = p.D456Y on NM_144686.4) | Missense Mutation (SNP) | VAF 149/392 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as rs751642758; called by muse, mutect2, varscan2
- ATP13A4 | c.2260G>A p.A754T | Missense Mutation (SNP) | VAF 165/414 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDKL5 | c.781_783dup p.R261dup | In Frame Ins (INS) | VAF 46/76 reads (61%) | called by mutect2, varscan2
- PNLIP | c.1252A>G p.I418V | Missense Mutation (SNP) | VAF 127/320 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZYG11B | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 87/256 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- MIPEP | c.291C>T p.S97= | Silent (SNP) | VAF 160/401 reads (40%) | called by muse, mutect2, varscan2
- PCARE | c.1374C>G p.S458= | Silent (SNP) | VAF 114/326 reads (35%) | called by muse, varscan2
